Somatic mutation profile of cancer-model specimen HCM-BROD-0574-C71-85B (Adherent Cell Line, passage 8; aliquot HCM-BROD-0574-C71-85B-01D-A82H-36), derived from the primary tumor of HCMI case HCM-BROD-0574-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 80.3 years (29,312 days).
Specimen HCM-BROD-0574-C71-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf028c28-9b21-4e7d-aca9-1f48e87a6f57.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0574-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0574-C71-10A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69e55d16-60ef-4099-b657-49d52b34c606

The open-access MAF lists 122 somatic variants for this specimen: 88 protein-altering or splice-affecting, 30 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 30, Nonsense Mutation 6, Intron 3, Frame Shift Del 3, Splice Site 2, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5428G>A p.D1810N | Missense Mutation (SNP) | VAF 228/228 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775912475, COSV58615443, COSV58615662, COSV58615890; called by muse, mutect2, varscan2
- EGFR | c.323G>A p.R108K | Missense Mutation (SNP) | VAF 666/4586 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519828, COSV51766433; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EGFR | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 670/5148 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139236063, COSV51769031, COSV51808387; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACR | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 286/721 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); catalogued as rs748831621, COSV99334535; called by muse, mutect2, varscan2
- AGTR1 | c.674C>A p.A225D | Missense Mutation (SNP) | VAF 104/217 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV62557822; called by muse, mutect2, varscan2
- ARHGEF26 | c.2587C>T p.R863C | Missense Mutation (SNP) | VAF 81/434 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1256404209; called by muse, mutect2, varscan2
- ARID5B | c.1564C>T p.Q522* | Nonsense Mutation (SNP) | VAF 245/245 reads (100%) | catalogued as COSV54418670; called by muse, mutect2, varscan2
- CHGB | c.829C>T p.R277* | Nonsense Mutation (SNP) | VAF 265/564 reads (47%) | catalogued as rs553869356, COSV66759863; called by muse, mutect2, varscan2
- DOCK5 | c.836C>A p.A279E | Missense Mutation (SNP) | VAF 156/304 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV99377804; called by muse, mutect2, varscan2
- EHD3 | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 43/552 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs200093466; called by muse, mutect2
- FAT2 | c.730G>A p.V244I | Missense Mutation (SNP) | VAF 313/658 reads (48%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs772062241; called by muse, mutect2
- FLT1 | c.3770G>T p.R1257L | Missense Mutation (SNP) | VAF 156/330 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV56734706; called by muse, varscan2
- IGHG1 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 278/346 reads (80%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.902); catalogued as rs778627526; called by muse, varscan2
- IRGQ | c.1304G>A p.R435Q | Missense Mutation (SNP) | VAF 420/759 reads (55%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as rs1329327460, COSV104414042; called by muse, mutect2, varscan2
- KLC3 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 193/370 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.699); catalogued as rs1302917549, COSV67270388, COSV67270976; called by mutect2, varscan2
- KMT2C | c.5198C>T p.S1733L | Missense Mutation (SNP) | VAF 322/511 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as rs146495785, COSV51499462, COSV99030941; called by muse, mutect2, varscan2
- LGSN | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 256/518 reads (49%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as rs770492942, COSV65727855; called by muse, mutect2, varscan2
- MATN4 | c.1567G>A p.V523M (on ENST00000372754; = p.V482M on NM_003833.4) | Missense Mutation (SNP) | VAF 324/631 reads (51%) | PolyPhen probably damaging (0.996); catalogued as rs748470059, COSV61352149; called by muse, mutect2, varscan2
- MBD1 | c.1090G>A p.G364S (on ENST00000269468 / NM_001323950.1; = p.G341S on NM_015845.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 322/642 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54005193; called by muse, mutect2, varscan2
- MYH13 | c.2173C>T p.R725W | Missense Mutation (SNP) | VAF 159/386 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs902590181, COSV99354977; called by muse, mutect2, varscan2
- NLRP5 | c.2386C>T p.R796W | Missense Mutation (SNP) | VAF 48/712 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs144876069, COSV66761951; called by muse, mutect2
- NPHS1 | c.17C>T p.T6M | Missense Mutation (SNP) | VAF 275/548 reads (50%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs150180768; called by muse, mutect2, varscan2
- OR1L1 | c.619C>G p.L207V (on ENST00000373686; = p.L157V on NM_001005236.3) | Missense Mutation (SNP) | VAF 276/400 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs769163962; called by muse, mutect2, varscan2
- OTOR | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 157/358 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1413277935, COSV55722250, COSV55723260; called by muse, varscan2
- PAQR3 | c.587C>T p.T196M | Missense Mutation (SNP) | VAF 213/409 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.65); catalogued as rs1246093505, COSV55011653, COSV99785083; called by muse, mutect2, varscan2
- PCDH11X | c.2940G>T p.K980N | Missense Mutation (SNP) | VAF 214/277 reads (77%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); catalogued as rs867779875, COSV53507074; called by muse, mutect2, varscan2
- PDPR | c.2132G>A p.R711H | Missense Mutation (SNP) | VAF 176/512 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs572625758, COSV55354393; called by muse, mutect2, varscan2
- PEAR1 | c.2903G>A p.R968Q | Missense Mutation (SNP) | VAF 56/690 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs781413106; called by muse, mutect2
- PYGB | c.619G>A p.V207M | Missense Mutation (SNP) | VAF 202/444 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs201689841; called by muse, mutect2, varscan2
- RAPGEF5 | c.614G>A p.R205H (on ENST00000401957 / NM_001367602.2; = p.R508H on NM_012294.5) | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as rs970302956, COSV59785740; called by muse, mutect2, varscan2
- RETREG2 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 200/427 reads (47%) | SIFT tolerated (1); PolyPhen possibly damaging (0.696); catalogued as COSV99811483; called by muse, mutect2, varscan2
- RYR2 | c.13900G>A p.V4634I | Missense Mutation (SNP) | VAF 104/317 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs756310498, COSV63666877; called by muse, mutect2, varscan2
- SEMA3C | c.1588C>A p.P530T | Missense Mutation (SNP) | VAF 173/664 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54851645; called by muse, mutect2, varscan2
- SERPINA7 | c.875G>A p.W292* | Nonsense Mutation (SNP) | VAF 213/213 reads (100%) | catalogued as rs902678899, COSV59665870; called by muse, mutect2, varscan2
- SLC44A3 | c.885G>A p.T295= (on ENST00000271227 / NM_001114106.3; = p.T247= on NM_152369.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 160/299 reads (54%) | catalogued as rs144117916; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1921C>T p.R641* (on ENST00000540229 / NM_001371097.1; = p.R580* on NM_001009562.4) | Nonsense Mutation (SNP) | VAF 122/263 reads (46%) | catalogued as rs752627008, COSV67441851; called by muse, mutect2, varscan2
- THBS1 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 333/685 reads (49%) | SIFT tolerated (0.48); PolyPhen benign (0.096); catalogued as rs1236362449, COSV52953588, COSV52955289; called by muse, mutect2, varscan2
- TMEM236 | c.835C>T p.R279* | Nonsense Mutation (SNP) | VAF 222/222 reads (100%) | catalogued as rs1270327044; called by muse, mutect2, varscan2
- TNF | c.619C>T p.R207* | Nonsense Mutation (SNP) | VAF 457/947 reads (48%) | catalogued as COSV69304535; called by muse, mutect2, varscan2
- TOM1 | c.457A>G p.M153V | Missense Mutation (SNP) | VAF 261/501 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as rs377560801; called by muse, mutect2, varscan2
- TOX | c.898G>T p.D300Y | Missense Mutation (SNP) | VAF 112/281 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63847616; called by muse, mutect2, varscan2
- XKR8 | c.1027C>T p.P343S | Missense Mutation (SNP) | VAF 24/759 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100872006; called by muse, mutect2
- AC004922.1 | c.1322_1326del p.N441Ifs*20 | Frame Shift Del (DEL) | VAF 152/710 reads (21%) | called by pindel, varscan2
- ARID2 | c.3223G>T p.G1075C | Missense Mutation (SNP) | VAF 79/479 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP1A2 | c.149G>A p.G50D | Missense Mutation (SNP) | VAF 128/348 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- C2orf16 | c.269C>A p.S90Y | Missense Mutation (SNP) | VAF 138/437 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- CASD1 | c.1231G>T p.V411F | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- CELA2A | c.763G>C p.V255L | Missense Mutation (SNP) | VAF 253/559 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL6A5 | c.5319C>A p.S1773R (on ENST00000312481; = p.S1769R on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 154/356 reads (43%) | SIFT tolerated (0.78); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CROCC | c.3617G>A p.G1206D | Missense Mutation (SNP) | VAF 440/935 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- DCDC1 | c.2482C>T p.P828S | Missense Mutation (SNP) | VAF 188/408 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- EPG5 | c.3896T>C p.L1299P | Missense Mutation (SNP) | VAF 19/619 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- F2RL3 | c.59C>T p.T20I | Missense Mutation (SNP) | VAF 278/609 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FBXL17 | c.466G>T p.G156C | Missense Mutation (SNP) | VAF 225/951 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, varscan2
- GLI2 | c.1462del p.C488Afs*16 (on ENST00000361492 / NM_001374353.1; = p.C505Afs*16 on NM_005270.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 168/457 reads (37%) | called by mutect2, pindel, varscan2
- GON4L | c.70A>T p.N24Y | Missense Mutation (SNP) | VAF 120/493 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- GPSM1 | c.1636C>G p.P546A | Missense Mutation (SNP) | VAF 278/278 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- GREM2 | c.256G>T p.G86C | Missense Mutation (SNP) | VAF 307/917 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GSK3B | c.282+1G>A p.X94_splice | Splice Site (SNP) | VAF 108/196 reads (55%) | called by muse, mutect2, varscan2
- HLA-DOB | c.5G>C p.G2A | Missense Mutation (SNP) | VAF 56/417 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- IGKV2-30 | c.181T>G p.F61V | Missense Mutation (SNP) | VAF 221/475 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- IL12A | c.535C>G p.L179V | Missense Mutation (SNP) | VAF 166/348 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- LYST | c.1291G>T p.D431Y | Missense Mutation (SNP) | VAF 185/613 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- MRTFA | c.1696G>A p.G566S | Missense Mutation (SNP) | VAF 401/832 reads (48%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- MUC4 | c.5374C>G p.R1792G | Missense Mutation (SNP) | VAF 256/1206 reads (21%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.158); called by muse, varscan2
- NOVA2 | c.1085C>T p.A362V | Missense Mutation (SNP) | VAF 107/234 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NPAP1 | c.1609T>C p.S537P | Missense Mutation (SNP) | VAF 123/525 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- NRXN3 | c.1184C>T p.S395F (on ENST00000335750 / NM_001330195.2; = p.S22F on NM_004796.6) | Missense Mutation (SNP) | VAF 210/210 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NTHL1 | c.70G>A p.G24R (on ENST00000219066; = p.G16R on NM_002528.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 440/613 reads (72%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- OBSCN | c.10868-1G>T p.X3623_splice | Splice Site (SNP) | VAF 26/384 reads (7%) | called by muse, mutect2
- OR8J2 | c.163C>A p.L55I | Missense Mutation (SNP) | VAF 45/373 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- OTOG | c.4537C>G p.P1513A | Missense Mutation (SNP) | VAF 389/845 reads (46%) | SIFT tolerated (0.52); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- PHC1 | c.2024A>G p.E675G | Missense Mutation (SNP) | VAF 55/298 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- PKD1L1 | c.411A>T p.K137N | Missense Mutation (SNP) | VAF 93/445 reads (21%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- PKHD1 | c.4894G>A p.G1632S | Missense Mutation (SNP) | VAF 236/470 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PODXL2 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 249/541 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- PRAM1 | c.1108C>T p.P370S | Missense Mutation (SNP) | VAF 253/626 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PRKAR1B | c.904G>A p.V302M | Missense Mutation (SNP) | VAF 44/1022 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- PZP | c.541A>C p.K181Q | Missense Mutation (SNP) | VAF 189/376 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- SH3RF3 | c.479C>T p.T160I | Missense Mutation (SNP) | VAF 397/754 reads (53%) | SIFT tolerated (0.29); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SLC34A2 | c.715C>T p.H239Y | Missense Mutation (SNP) | VAF 226/424 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- SLCO1A2 | c.535G>C p.G179R | Missense Mutation (SNP) | VAF 165/344 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SMAP1 | c.530_533del p.R177Kfs*42 (on ENST00000370455 / NM_001044305.3; = p.R150Kfs*42 on NM_021940.5) | Frame Shift Del (DEL) | VAF 53/162 reads (33%) | called by mutect2, pindel, varscan2
- TAF1B | c.1535A>G p.Y512C | Missense Mutation (SNP) | VAF 119/397 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRIM77 | c.1310T>C p.F437S | Missense Mutation (SNP) | VAF 180/348 reads (52%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); called by muse, varscan2
- USP26 | c.248T>C p.I83T | Missense Mutation (SNP) | VAF 99/198 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- VSIG10 | c.1032G>C p.W344C | Missense Mutation (SNP) | VAF 272/583 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF578 | c.1519G>A p.G507S | Missense Mutation (SNP) | VAF 118/281 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCZ1B | c.30C>T p.S10= | Silent (SNP) | VAF 58/832 reads (7%) | catalogued as rs1208874822; called by muse, mutect2
- CD209 | c.834C>T p.H278= | Silent (SNP) | VAF 204/486 reads (42%) | catalogued as rs61742035, COSV52654363; called by muse, mutect2, varscan2
- CHRNB3 | c.381C>G p.G127= | Silent (SNP) | VAF 153/312 reads (49%) | called by muse, mutect2, varscan2
- CLEC4M | c.1011C>T p.G337= | Silent (SNP) | VAF 116/350 reads (33%) | called by muse, mutect2, varscan2
- CLSPN | c.3213T>C p.Y1071= | Silent (SNP) | VAF 232/491 reads (47%) | called by muse, mutect2, varscan2
- CUX1 | c.1212C>T p.S404= (on ENST00000292535 / NM_181552.4; = p.S415= on NM_001913.5) | Silent (SNP) | VAF 124/729 reads (17%) | catalogued as rs782775542, COSV52891917; called by muse, mutect2, varscan2
- DSG1 | c.1836C>T p.V612= | Silent (SNP) | VAF 100/264 reads (38%) | called by muse, mutect2, varscan2
- FERMT3 | c.552C>T p.H184= | Silent (SNP) | VAF 355/745 reads (48%) | called by muse, mutect2, varscan2
- GCGR | c.474C>T p.L158= | Silent (SNP) | VAF 288/623 reads (46%) | catalogued as rs372925021; called by muse, mutect2, varscan2
- GPRASP1 | c.2724G>A p.G908= | Silent (SNP) | VAF 34/286 reads (12%) | called by muse, mutect2, varscan2
- HGF | c.726G>T p.R242= | Silent (SNP) | VAF 69/500 reads (14%) | catalogued as COSV55959010; called by muse, mutect2, varscan2
- KCNMB1 | c.333C>T p.D111= | Silent (SNP) | VAF 234/542 reads (43%) | called by muse, mutect2
- KHDRBS3 | c.885C>A p.A295= | Silent (SNP) | VAF 19/319 reads (6%) | catalogued as COSV63419672; called by muse, mutect2
- KSR1 | c.2289C>T p.R763= (on ENST00000644974 / NM_001367810.1; = p.R648= on NM_014238.2) | Silent (SNP) | VAF 134/316 reads (42%) | catalogued as rs369797872; called by muse, mutect2, varscan2
- LRP1 | c.636G>C p.T212= | Silent (SNP) | VAF 268/553 reads (48%) | catalogued as rs760353175, COSV54524071; called by muse, mutect2, varscan2
- LRRC15 | c.1410C>T p.N470= | Silent (SNP) | VAF 161/371 reads (43%) | catalogued as rs764925067, COSV61650559; called by muse, mutect2, varscan2
- MMUT | c.201C>T p.I67= | Silent (SNP) | VAF 256/539 reads (47%) | catalogued as COSV51272384; called by muse, mutect2, varscan2
- MUC16 | c.11442C>T p.S3814= | Silent (SNP) | VAF 214/431 reads (50%) | called by muse, mutect2, varscan2
- MUC4 | c.12555A>G p.A4185= | Silent (SNP) | VAF 18/704 reads (3%) | catalogued as rs568455054; called by muse, mutect2
- OR5M1 | c.171A>C p.T57= | Silent (SNP) | VAF 204/447 reads (46%) | called by muse, mutect2, varscan2
- OR6F1 | c.396C>T p.Y132= | Silent (SNP) | VAF 396/631 reads (63%) | catalogued as rs781296494, COSV57467097; called by muse, mutect2, varscan2
- PKD1 | c.12486C>T p.P4162= (on ENST00000262304 / NM_001009944.3; = p.P4161= on NM_000296.4) | Silent (SNP) | VAF 383/571 reads (67%) | catalogued as rs759210811; called by muse, mutect2, varscan2
- PTPRN2 | c.2691C>T p.T897= | Silent (SNP) | VAF 212/692 reads (31%) | called by muse, mutect2, varscan2
- SDK1 | c.324G>A p.T108= | Silent (SNP) | VAF 168/434 reads (39%) | catalogued as rs934988272, COSV101268829; called by muse, mutect2, varscan2
- SETD6 | c.93G>A p.R31= | Silent (SNP) | VAF 66/571 reads (12%) | called by muse, mutect2, varscan2
- SLC18A3 | c.366G>C p.V122= | Silent (SNP) | VAF 345/345 reads (100%) | called by muse, mutect2, varscan2
- TRIM47 | c.792G>A p.R264= | Silent (SNP) | VAF 296/595 reads (50%) | catalogued as rs1411101203; called by muse, mutect2, varscan2
- TRIM51 | c.111C>T p.P37= | Silent (SNP) | VAF 189/384 reads (49%) | catalogued as COSV55264603, COSV55270389; called by muse, mutect2, varscan2
- WDR97 | c.4488G>A p.A1496= | Silent (SNP) | VAF 312/563 reads (55%) | called by muse, mutect2, varscan2
- ZNF829 | c.114G>A p.R38= | Silent (SNP) | VAF 172/324 reads (53%) | catalogued as rs934241382; called by muse, mutect2, varscan2
- DCHS2 | n.8562C>T | RNA (SNP) | VAF 216/481 reads (45%) | catalogued as rs759791153, COSV61767417; called by muse, mutect2, varscan2
- FARP1 | c.1414+168G>A | Intron (SNP) | VAF 231/462 reads (50%) | catalogued as rs1431620505; called by muse, mutect2, varscan2
- KCNQ1 | c.1514+9584A>G | Intron (SNP) | VAF 22/452 reads (5%) | called by muse, mutect2
- ST3GAL3 | c.164-20189C>A | Intron (SNP) | VAF 172/393 reads (44%) | called by muse, mutect2, varscan2
